Gene-level copy-number profile of tumor specimen MP2PRT-PATNLF-TTR1-A from MP2PRT case MP2PRT-PATNLF, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.7 years (1,004 days).
Specimen MP2PRT-PATNLF-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8732a644-f303-4f72-aa86-533a561b28ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATNLF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/47058e49-f737-4e6c-9a29-4598ee10553f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 4,224; copy number 2: 36,885; copy number 3: 15,662; copy number 4: 498; copy number 5: 1,032; copy number 6: 100; copy number 7: 275; copy number 8: 91; copy number 9: 127.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,625 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:106,818,224–167,022,214, 1,288 genes, copy number 5–9 (broad region; genes not listed).
- chr1:168,079,543–173,921,200, 134 genes, copy number 5–7 (broad region; genes not listed).
- chr1:203,475,806–210,246,631, 174 genes, copy number 7–8 (broad region; genes not listed).
- chr2:89,985,922–91,621,421, 29 genes, copy number 5–6 (within-gene range 3–6): IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.

Autosomal genes at a single copy (total copy number 1): 1,424. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
